Somatic mutation profile of tumor specimen TARGET-20-PATENX-09A (aliquot TARGET-20-PATENX-09A-01D) from TARGET case TARGET-20-PATENX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 21.7 years (7,919 days).
Specimen TARGET-20-PATENX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85e72ca9-8167-49e4-b948-23d7e5104997.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATENX-14A (Bone Marrow Normal), aliquot TARGET-20-PATENX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e8a3875-75e4-4ef1-b80b-c170cc3c1b70

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH11 | c.*792C>A | 3'UTR (SNP) | VAF 111/293 reads (38%) | called by muse, mutect2, varscan2
- PCDH9 | c.-193G>A | 5'UTR (SNP) | VAF 14/388 reads (4%) | called by muse, mutect2
